Somatic mutation profile of tumor specimen TARGET-10-PAPFFW-09A (aliquot TARGET-10-PAPFFW-09A-01D) from TARGET case TARGET-10-PAPFFW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,148 days).
Specimen TARGET-10-PAPFFW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05dd772a-2234-41f5-a5af-ca03ab544abc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPFFW-14A (Bone Marrow Normal), aliquot TARGET-10-PAPFFW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c658549-d8d9-4ec0-a434-19fc3d0d3778

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PKHD1L1 | c.7927C>G p.P2643A | Missense Mutation (SNP) | VAF 7/195 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as COSV65744402; called by muse, mutect2
- ZFHX4 | c.10454A>T p.E3485V | Missense Mutation (SNP) | VAF 43/309 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1449035542; called by muse, mutect2, varscan2
- ADRB2 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- CENPE | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP4 | c.2488T>C p.F830L | Missense Mutation (SNP) | VAF 44/295 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DDX31 | c.1678G>C p.G560R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- UBE2D3 | c.66_67insCC p.A23Pfs*31 | Frame Shift Ins (INS) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- FAM227B | c.441+351G>T | Intron (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- NEBL | c.1117-41G>C | Intron (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
